Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7409, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7409-01A (Primary Tumor).

[page 1 of 2]
History Case Pathology Report

DOB:

Sex: M

Physician:

Accession:

** Case imported from legacy computer system. The format of this report does not match the original case. **
** For cases prior to November 1, 1997, the section "SPECIMEN" may have been added. **

DIAGNOSIS

(A) TRACHEAL STOMA:

skeletal muscle and fibroconnective tissue with granulation tissue, foreign body giant cell reaction and ulcer, no tumor present.

(B) RIGHT MODIFIED NECK DISSECTION, TOTAL LARYNGECTOMY, PARTIAL PHARYNGECTOMY, RIGHT THYROIDECTOMY AND LEFT MODIFIED NECK DISSECTION: INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA INVOLVING THE EPIGLOTTIS, PRE-EPIGLOTTIC SPACE, BASE OF TONGUE, AND ANTERIOR SOFT TISSUE; DEPTH OF INVASION 3.0 CM; LYMPHATIC INVASION PRESENT; MARGINS OF RESECTION FREE OF TUMOR.

Thyroid, no tumor present.

METASTATIC SQUAMOUS CARCINOMA IN 3 OF 48 RIGHT CERVICAL LYMPH NODES

(1/11 SUBDIGASTRIC, 1/6 MIDJUGULAR, 0/12 LOWER JUGULAR, 0/4 UPPER POSTERIOR CERVICAL, 1/2 MID POSTERIOR CERVICAL, 0/3 LOWER POSTERIOR CERVICAL, 0/8 SUPRACLAVICULAR-SCALENE, 0/3 THYROID THYROID COMPARTMENT.

METASTATIC SQUAMOUS CARCINOMA IN 4 OF 3 LEFT CERVICAL LYMPH NODES

(1/3 SUBDIGASTRIC, 2/6 JUGULAR, 1/1 MIDJUGULAR, 0/3 UPPER POSTERIOR CERVICAL.

Thyroid, no tumor present.

(C) MUCOSAL MARGIN OF TONGUE:

Squamous mucosa and submucosa, no tumor present.

(D) RIGHT PYRIFORM SINUS:

Squamous mucosa with chronic inflammation, no tumor present.

(E) CRICOID:

Squamous mucosa, no tumor present.

(F) LEFT PHARYNX:

Squamous mucosa, no tumor present.

(G) LEFT PYRIFORM:

Squamous mucosa, no tumor present.

(H) TRACHEAL MUCOSA:

Partially denuded trachea, no tumor present.

(I) RIGHT TONSIL:

Squamous mucosa and submucosa, no tumor present.

(J) RIGHT PHARYNX:

Squamous mucosa and skeletal muscle, no tumor present.

(K) TEETH:

Teeth and tooth fragments, no pathologic diagnosis (gross only).

COMMENT

The tumor measured 8.0 x 6.5 x 3.0 cm and had an epicenter in the epiglottis. It extended beyond the thyroid cartilage into the anterior soft tissue (depth 3.0 cm). Decalcified sections of the hyoid bone show focal bone invasion by squamous carcinoma. The largest lymph node metastasis measured 4.0 cm (right subdigastric and right midjugular) each with focal extranodal extension into the adjacent jugular vein wall (Code: B21).

[page 2 of 2]
History Case Pathology Report

DOB.

Sex: M

Physician:

Accession:

SPECIMEN

- (A) TRACHEAL STOMA:
- (B) RIGHT MODIFIED NECK DISSECTION, TOTAL LARYNGECTOMY, PARTIAL
- (C) MUCOSAL MARGIN OF TONGUE:
- (D) RIGHT PYRIFORM SINUS:
- (E) CRICOID:
- (F) LEFT PHARYNX:
- (G) LEFT PYRIFORM:
- (H) TRACHEAL MUCOSA:
- (I) RIGHT TONSIL:
- (J) RIGHT PHARYNX:
- (K) TEETH:

Source: NCI Genomic Data Commons file 6912960c-a82b-47be-acf5-ee90f08623dc (TCGA-CV-7409.EB374C5B-EE79-4430-9FDD-A132C505D3D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).